Somatic mutation profile of tumor specimen TCGA-B5-A3FA-01A (aliquot TCGA-B5-A3FA-01A-11D-A19Y-09) from TCGA case TCGA-B5-A3FA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 73.5 years (26,850 days).
Specimen TCGA-B5-A3FA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3037f4b3-f668-45f1-9b34-e7d00031bc5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A3FA-10A (Blood Derived Normal), aliquot TCGA-B5-A3FA-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ab98804-ad0f-4ebf-9035-578b4eb0e4ad

The open-access MAF lists 11,645 somatic variants for this specimen: 8,508 protein-altering or splice-affecting, 2,837 silent, 300 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7,588, Silent 2,837, Nonsense Mutation 452, Splice Site 189, Intron 128, Splice Region 111, Frame Shift Ins 101, RNA 77, Frame Shift Del 52, 3'UTR 36, 5'Flank 22, 5'UTR 19.

Variants (750 of 11,645; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.1176+2T>C p.X392_splice | Splice Site (SNP) | VAF 24/58 reads (41%) | catalogued as rs750586210, CS078142; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as rs199422227, CM920368, COSV61712686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.223T>C p.W75R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555453695; ClinVar: pathogenic; called by muse, mutect2
- ASS1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as rs183276875, CM034723; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CFTR | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs121908749, CM126469, CM940236, COSV99141556; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1005dup p.E336* | Frame Shift Ins (INS) | VAF 10/55 reads (18%) | catalogued as rs1554611860; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DCX | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 55/158 reads (35%) | catalogued as rs587783592, CM980536, COSV57575875; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDC | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137853212, CM984683, COSV63564689; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- EDA | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs132630312, CM980583, COSV65772037; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EP300 | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as rs1555911075, CM151330, COSV54328581; ClinVar: pathogenic; called by muse, varscan2
- FAT1 | c.4879C>T p.R1627* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | hotspot (GDC flag); catalogued as rs1340793072, COSV71673166; called by muse, mutect2, varscan2
- HPRT1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs387906725, CM920351, COSV100053047; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPSE2 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as rs267606866, CM103331, COSV65181961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD17B3 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs119481075, CM940950; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.4048C>T p.R1350* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs756854513, CM102055, COSV70343609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEF2C | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as rs796052733, COSV60928469; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEF2C | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 61/138 reads (44%) | catalogued as rs587783747, COSV100424590, COSV60937894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.2147+2T>C p.X716_splice | Splice Site (SNP) | VAF 7/17 reads (41%) | catalogued as rs1555984946; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 32/69 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3061T>C p.Y1021H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV55901519, COSV55910253; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 43/48 reads (90%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 40/128 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.5644C>T p.R1882* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as rs796053166, CM162377, COSV99334228; ClinVar: pathogenic; called by muse, varscan2
- SDHB | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138996609, CM034573, COSV64965126; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SGCD | c.781G>A p.E261K (on ENST00000435422 / NM_001128209.2; = p.E262K on NM_000337.5) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs121909297, CM981794, COSV61911296; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC2A2 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs121909741, CM941278; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SUZ12 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | hotspot (GDC flag); catalogued as rs2627175; called by muse, mutect2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBCD | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764085684, COSV62805612; ClinVar: pathogenic; called by muse, varscan2
- TP63 | c.1681T>G p.C561G | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121908843, CM010362, CM114645; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- A2ML1 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs1160627568, COSV55286815; called by muse, mutect2, varscan2
- A2ML1 | c.3092G>T p.G1031V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV55294995; called by muse, mutect2, varscan2
- A4GALT | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs1419657104; called by muse, mutect2
- AADACL2 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | catalogued as rs201287466, COSV62929985; called by muse, mutect2, varscan2
- AARS2 | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as rs1158769036, COSV99771680; called by muse, mutect2
- ABCA1 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs139734524, CM140757, COSV66070588; called by muse, mutect2, varscan2
- ABCA1 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV66065648; called by muse, varscan2
- ABCA10 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs776740985; called by muse, mutect2, varscan2
- ABCA12 | c.4618G>A p.A1540T (on ENST00000272895 / NM_173076.3; = p.A1222T on NM_015657.3) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771394858; called by muse, mutect2, varscan2
- ABCA12 | c.4279G>A p.D1427N (on ENST00000272895 / NM_173076.3; = p.D1109N on NM_015657.3) | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.652); catalogued as rs761801135; called by muse, mutect2, varscan2
- ABCA12 | c.4033G>A p.G1345R (on ENST00000272895 / NM_173076.3; = p.G1027R on NM_015657.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745333434, COSV55949543, COSV55974018; called by muse, mutect2, varscan2
- ABCA12 | c.2025G>T p.E675D (on ENST00000272895 / NM_173076.3; = p.E357D on NM_015657.3) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as CD065656, COSV99788104; called by muse, mutect2, varscan2
- ABCA13 | c.8021G>A p.R2674Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs748507270; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2
- ABCA5 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.174); catalogued as COSV67016284; called by muse, mutect2, varscan2
- ABCA6 | c.2646G>T p.K882N | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV52636891; called by muse, mutect2, varscan2
- ABCA8 | c.693T>G p.I231M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.506); catalogued as COSV99285385; called by muse, mutect2, varscan2
- ABCA8 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.124); catalogued as COSV104393365; called by muse, mutect2, varscan2
- ABCA9 | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs772870876, COSV100383418, COSV60630364; called by muse, mutect2, varscan2
- ABCB1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs763454753; called by muse, varscan2
- ABCB11 | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV55590482; called by muse, mutect2, varscan2
- ABCB5 | c.432dup p.H145Sfs*12 | Frame Shift Ins (INS) | VAF 24/118 reads (20%) | catalogued as rs1434999011; called by mutect2, varscan2
- ABCB5 | c.3475G>A p.G1159S (on ENST00000404938 / NM_001163941.2; = p.G714S on NM_178559.6) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs142824450; called by muse, mutect2, varscan2
- ABCB6 | c.2452T>C p.Y818H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004119780; called by muse, mutect2, varscan2
- ABCB9 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.608); catalogued as rs778838893; called by muse, mutect2, varscan2
- ABCC1 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs757068084; called by muse, mutect2, varscan2
- ABCC1 | c.2068G>T p.A690S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100579584; called by muse, mutect2, varscan2
- ABCC11 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371302823, COSV62322509; called by muse, mutect2, varscan2
- ABCC12 | c.1236+2T>C p.X412_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as rs746792798; called by muse, mutect2, varscan2
- ABCC3 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53324158; called by muse, mutect2, varscan2
- ABCC4 | c.3682G>A p.V1228M | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs141672372; called by muse, mutect2, varscan2
- ABCC8 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as CM085200, COSV56854527; called by muse, mutect2, varscan2
- ABCC9 | c.3277C>A p.L1093I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53977857; called by muse, mutect2, varscan2
- ABCF1 | c.492C>T p.A164= | Splice Region (SNP) | VAF 22/52 reads (42%) | catalogued as rs779273946; called by muse, mutect2, varscan2
- ABCF2 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs369843747; called by muse, mutect2, varscan2
- ABHD12B | c.343G>A p.V115I (on ENST00000337334 / NM_001206673.2; = p.V38I on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as rs1424349396; called by muse, mutect2, varscan2
- ABHD13 | c.558A>C p.K186N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV65535464; called by muse, mutect2, varscan2
- ABHD14B | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751636953; called by muse, mutect2
- ABHD17B | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs1418324019, COSV61008478; called by muse, mutect2, varscan2
- ABHD18 | c.1150C>T p.R384* (on ENST00000398965 / NM_001039717.2; = p.R291* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as rs1355205312, COSV66293606; called by muse, mutect2, varscan2
- ABHD3 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs148684195; called by muse, mutect2, varscan2
- ABLIM2 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1459832941; called by muse, mutect2, varscan2
- AC004593.2 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs1169216156, COSV56090056; called by muse, varscan2
- AC004922.1 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.995); catalogued as rs763123089; called by muse, mutect2, varscan2
- AC013477.1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.009); catalogued as rs560093783, COSV53654433; called by muse, varscan2
- AC091959.1 | c.3015A>C p.Q1005H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as rs1324370803; called by muse, mutect2
- AC092143.1 | c.2105A>C p.D702A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59247410; called by muse, mutect2, varscan2
- ACACB | c.5368G>A p.V1790I | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.163); catalogued as rs1381125002; called by muse, mutect2, varscan2
- ACAN | c.4573C>A p.L1525I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.279); catalogued as rs1185863833; called by muse, mutect2, varscan2
- ACAP2 | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867497776; called by muse, mutect2
- ACE | c.2357C>G p.A786G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV52013504; called by muse, mutect2
- ACE2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs1348114695; called by muse, mutect2, varscan2
- ACIN1 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV52972936, COSV52973539; called by muse, varscan2
- ACO2 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.078); catalogued as rs142767544; ClinVar: uncertain significance; called by muse, varscan2
- ACOT9 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs146707213, COSV60537735; called by muse, mutect2, varscan2
- ACSBG2 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1407806071, COSV53124536; called by muse, mutect2, varscan2
- ACSL3 | c.556+1G>A p.X186_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as rs200677606; called by muse, mutect2, varscan2
- ACSL3 | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.974); catalogued as rs781374154; called by muse, mutect2, varscan2
- ACTA1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as CM034495, COSV64204280; called by muse, mutect2, varscan2
- ACTL6B | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1324552122; called by muse, mutect2, varscan2
- ACTN2 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV63975496; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR6 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751590872, COSV51843879; called by muse, mutect2, varscan2
- ACTRT2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs755674205, COSV65759059; called by muse, mutect2, varscan2
- ACVR1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316254232, COSV55122676; called by muse, varscan2
- ACVR1C | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs758359984; called by muse, mutect2, varscan2
- ADA | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908718, CM890002; called by muse, mutect2, varscan2
- ADA2 | c.542+1G>A p.X181_splice | Splice Site (SNP) | VAF 37/90 reads (41%) | catalogued as rs778864321; called by muse, mutect2, varscan2
- ADAM12 | c.2206C>T p.R736* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as rs745628072, COSV64104548; called by muse, mutect2, varscan2
- ADAM20 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV56456734; called by muse, mutect2, varscan2
- ADAM22 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs374141909, COSV55983486; called by muse, mutect2, varscan2
- ADAM32 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs567675296, COSV65946823; called by muse, mutect2, varscan2
- ADAM32 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1020309518; called by muse, mutect2, varscan2
- ADAM9 | c.867A>C p.E289D | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV65946766; called by muse, mutect2, varscan2
- ADAMTS12 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761157092, COSV61257360, COSV61262119; called by muse, mutect2, varscan2
- ADAMTS18 | c.2641G>A p.V881M | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs147244223; called by muse, mutect2, varscan2
- ADAMTS20 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs372581152; called by muse, mutect2, varscan2
- ADAMTS3 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs756243336; called by muse, mutect2, varscan2
- ADAMTS5 | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs777065435, COSV53177958; called by muse, varscan2
- ADAMTSL1 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs151019079, COSV99443478; called by muse, mutect2, varscan2
- ADAMTSL3 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as rs771154300, COSV99721988; called by muse, mutect2, varscan2
- ADAP2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs956226574, COSV100437159; called by muse, mutect2, varscan2
- ADAT1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777652272, COSV57186153; called by muse, mutect2, varscan2
- ADCY1 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV52035439; called by muse, mutect2, varscan2
- ADCY4 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147496401; called by muse, mutect2, varscan2
- ADCY9 | c.3884C>T p.S1295F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as rs768979927; called by muse, mutect2, varscan2
- ADGRA3 | c.2836C>A p.P946T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51567252; called by muse, mutect2, varscan2
- ADGRE2 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs770915022, COSV100216525; called by muse, mutect2, varscan2
- ADGRE3 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99506755; called by muse, mutect2, varscan2
- ADGRF5 | c.1411+2T>C p.X471_splice | Splice Site (SNP) | VAF 6/84 reads (7%) | catalogued as COSV51937022; called by muse, mutect2
- ADGRG2 | c.304+1G>A p.X102_splice (on ENST00000379869 / NM_001079858.3; = p.X99_splice on NM_005756.4) | Splice Site (SNP) | VAF 9/121 reads (7%) | catalogued as rs1158027165; called by muse, mutect2
- ADGRG3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs956876949; called by muse, mutect2, varscan2
- ADGRG4 | c.4508C>A p.S1503Y | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV54955283; called by muse, mutect2, varscan2
- ADGRG4 | c.6656C>T p.T2219I | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV54971841; called by muse, mutect2, varscan2
- ADGRG4 | c.8434G>A p.A2812T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs775340170; called by muse, mutect2, varscan2
- ADGRG7 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.055); catalogued as COSV56300428; called by muse, mutect2, varscan2
- ADGRL2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752679138, COSV54649550; called by mutect2, varscan2
- ADGRL2 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557964932; called by muse, mutect2, varscan2
- ADGRL3 | c.3722G>A p.R1241Q (on ENST00000506720 / NM_001322402.2; = p.R1173Q on NM_015236.6) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs143689172; called by muse, mutect2, varscan2
- ADGRL4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs771201747, COSV66061203; called by muse, mutect2, varscan2
- ADGRV1 | c.4226A>G p.Y1409C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs751548859; called by muse, mutect2, varscan2
- ADGRV1 | c.7906G>T p.D2636Y | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67986369; called by muse, mutect2, varscan2
- ADGRV1 | c.10888G>T p.G3630* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV67986485; called by muse, mutect2, varscan2
- ADGRV1 | c.15928C>T p.R5310C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777578222, COSV67989499; called by muse, mutect2, varscan2
- ADH1C | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV72624780; called by muse, mutect2, varscan2
- ADH1C | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423604859, COSV101565191; called by muse, mutect2
- ADH6 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs61755961, COSV52955791; called by muse, mutect2, varscan2
- ADORA2A | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100418115; called by muse, mutect2, varscan2
- ADSS2 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100836839; called by muse, mutect2, varscan2
- AFAP1L2 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV100412124; called by muse, mutect2, varscan2
- AFDN | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs772507883; called by muse, mutect2, varscan2
- AFF2 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs929635504, COSV99662967; called by muse, mutect2, varscan2
- AFF2 | c.3883C>T p.R1295C | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557292233, COSV53997140; called by muse, mutect2, varscan2
- AGK | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1057521780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGO1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371043471; called by muse, mutect2, varscan2
- AGPS | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV51560584; called by muse, mutect2, varscan2
- AGTPBP1 | c.1147G>A p.E383K (on ENST00000357081 / NM_001330701.2; = p.E343K on NM_015239.2) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs538837935; called by muse, varscan2
- AGXT2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs1289298122, COSV51487805; called by muse, mutect2, varscan2
- AHI1 | c.3262T>C p.W1088R | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201270602; called by muse, mutect2, varscan2
- AHNAK | c.13876G>A p.E4626K | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.485); catalogued as rs762871549; called by muse, mutect2, varscan2
- AHNAK | c.12961A>G p.M4321V | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as rs1359673505; called by muse, mutect2, varscan2
- AHNAK | c.10044G>T p.K3348N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99946287, COSV99947809; called by muse, mutect2, varscan2
- AHNAK2 | c.15700G>T p.E5234* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as COSV60913634, COSV60922350; called by muse, mutect2, varscan2
- AHNAK2 | c.12161T>C p.V4054A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV60907180; called by muse, mutect2, varscan2
- AHNAK2 | c.6893C>T p.A2298V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.98); PolyPhen benign (0.24); catalogued as rs780710267, COSV60920631; called by muse, mutect2, varscan2
- AHNAK2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs762387018, COSV60914315; called by muse, mutect2, varscan2
- AHR | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs1037222277; called by muse, mutect2, varscan2
- AIFM1 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as CD102149, COSV54857484; called by muse, mutect2
- AKAP12 | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs1361173400; called by muse, mutect2, varscan2
- AKAP14 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57631378; called by muse, mutect2, varscan2
- AKAP3 | c.1610A>G p.Y537C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs767180671; called by muse, mutect2, varscan2
- AKAP6 | c.6536C>A p.S2179Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.185); catalogued as COSV104384199, COSV55225758; called by muse, mutect2, varscan2
- AKAP7 | c.236dup p.R80Efs*24 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs763109484; called by mutect2, varscan2
- AKAP9 | c.4696C>A p.H1566N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs886039037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.7805C>T p.S2602L (on ENST00000359028; = p.S2578L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV62355127; called by muse, mutect2, varscan2
- AKNAD1 | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779270486, COSV62198420; called by muse, mutect2, varscan2
- AKNAD1 | c.1576G>A p.G526S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1424849650, COSV104422444; called by muse, mutect2, varscan2
- AKR1B1 | c.741+2T>C p.X247_splice | Splice Site (SNP) | VAF 22/94 reads (23%) | catalogued as rs752192413; called by muse, mutect2, varscan2
- AKR1C4 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as rs370245703; called by muse, mutect2, varscan2
- AKR1C4 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781989291, COSV99578428; called by muse, mutect2, varscan2
- AKT3 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV55606102; called by muse, mutect2, varscan2
- AL121899.2 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs189594278, COSV67351365; called by muse, mutect2, varscan2
- ALG10B | c.735A>C p.K245N | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV58145158; called by muse, mutect2, varscan2
- ALG9 | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); catalogued as rs1421616277; called by muse, mutect2
- ALMS1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs776946280; called by muse, mutect2, varscan2
- ALMS1 | c.1642A>G p.T548A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as CD150676; called by muse, mutect2, varscan2
- ALMS1 | c.11411G>A p.R3804K | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as CD117968; called by muse, mutect2, varscan2
- ALOXE3 | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs750553644; called by muse, varscan2
- ALPK2 | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs767612056; called by muse, varscan2
- ALPK2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as rs565612566, COSV64490186; called by muse, mutect2, varscan2
- ALS2 | c.1895A>G p.Q632R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV51888897; called by muse, mutect2, varscan2
- ALS2CL | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.119); catalogued as rs1210565466; called by muse, mutect2, varscan2
- AMBRA1 | c.1594G>A p.E532K (on ENST00000458649 / NM_001367468.1; = p.E442K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV54048667; called by muse, mutect2, varscan2
- AMER3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1381313687, COSV58465747; called by muse, mutect2
- ANK2 | c.2662C>T p.R888* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as rs867072234, COSV52156015; called by muse, mutect2, varscan2
- ANK2 | c.3113C>A p.A1038D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52162669; called by muse, mutect2, varscan2
- ANK2 | c.9145C>T p.R3049W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201870166, COSV52158351; called by muse, varscan2
- ANK3 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs376032920; called by muse, mutect2, varscan2
- ANKAR | c.3941C>T p.A1314V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs774863513; called by muse, mutect2, varscan2
- ANKEF1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1056528269; called by muse, mutect2, varscan2
- ANKFN1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs183282741; called by muse, mutect2, varscan2
- ANKFY1 | c.2902G>A p.V968M (on ENST00000341657 / NM_001330063.2; = p.V969M on NM_016376.5) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs181388284; called by muse, mutect2, varscan2
- ANKK1 | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1184031581; called by muse, mutect2, varscan2
- ANKLE2 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs1474456637; called by muse, mutect2, varscan2
- ANKMY1 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs192205980, COSV56036921; called by muse, mutect2, varscan2
- ANKRD12 | c.2360C>A p.S787Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.054); catalogued as COSV50847396; called by mutect2, varscan2
- ANKRD13C | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.895); catalogued as rs774093011, COSV52035716; called by muse, mutect2, varscan2
- ANKRD2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs780214039, COSV53967739; called by muse, mutect2, varscan2
- ANKRD20A4P | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100628632; called by mutect2, varscan2
- ANKRD24 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378320340; called by muse, mutect2, varscan2
- ANKRD24 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs942620606, COSV53674213; called by muse, mutect2
- ANKRD26 | c.2562C>T p.V854= | Splice Region (SNP) | VAF 20/56 reads (36%) | catalogued as rs889042227, COSV65777881; called by muse, mutect2, varscan2
- ANKRD27 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs750530864, COSV100043124, COSV60130667; called by muse, mutect2, varscan2
- ANKRD30A | c.657G>T p.E219D (on ENST00000611781; = p.E163D on NM_052997.2) | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.874); catalogued as COSV64608110; called by muse, mutect2, varscan2
- ANKRD30A | c.2742del p.K914Nfs*38 (on ENST00000611781; = p.K858Nfs*38 on NM_052997.2) | Frame Shift Del (DEL) | VAF 64/198 reads (32%) | catalogued as COSV64617415, COSV64618048; called by mutect2, pindel, varscan2
- ANKRD36 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs537628459; called by muse, mutect2, varscan2
- ANKRD44 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs779440775; called by muse, mutect2, varscan2
- ANKS1A | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs906953823; called by muse, mutect2, varscan2
- ANKS1B | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs542524400; called by muse, mutect2, varscan2
- ANKS1B | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV61381694; called by muse, mutect2, varscan2
- ANKS4B | c.947C>A p.A316D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61139409; called by muse, mutect2, varscan2
- ANO10 | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV52735500; called by muse, mutect2, varscan2
- ANO2 | c.1437G>T p.Q479H (on ENST00000356134 / NM_001278597.3; = p.Q483H on NM_001278596.3) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV59040695; called by muse, mutect2, varscan2
- ANO2 | c.1156G>A p.A386T (on ENST00000356134 / NM_001278597.3; = p.A390T on NM_001278596.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.454); catalogued as COSV59009694; called by muse, mutect2, varscan2
- ANO3 | c.544A>G p.T182A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.146); catalogued as COSV56803965; called by muse, mutect2, varscan2
- ANO3 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1316389828, COSV56790103; called by muse, mutect2, varscan2
- ANO4 | c.2237G>A p.R746Q (on ENST00000392977 / NM_001286615.2; = p.R711Q on NM_178826.4) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748414275; called by muse, varscan2
- ANO5 | c.542A>G p.Y181C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); catalogued as rs915766003; called by muse, mutect2, varscan2
- ANO6 | c.2549T>C p.F850S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.277); catalogued as COSV100262595; called by muse, mutect2, varscan2
- ANXA8 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs1450074142; called by muse, mutect2, varscan2
- AOAH | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs150438169, COSV51737665; called by muse, mutect2, varscan2
- AP1B1 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as rs1297525814; called by muse, mutect2, varscan2
- AP3S1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as rs1226013093; called by muse, mutect2, varscan2
- AP4B1 | c.1358C>A p.A453D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99870719; called by muse, mutect2, varscan2
- AP4E1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375514846; called by muse, mutect2, varscan2
- AP4E1 | c.1018T>C p.C340R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs960774382; called by muse, mutect2, varscan2
- APAF1 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1259676865; called by muse, mutect2, varscan2
- APBA1 | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55227236; called by muse, mutect2, varscan2
- APC | c.2234C>A p.P745H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD106414, COSV57384164, COSV99965345; called by muse, mutect2, varscan2
- APC | c.3214A>G p.S1072G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as CD057021, COSV57332148; called by muse, mutect2, varscan2
- APC | c.5537A>G p.Y1846C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57390063; called by muse, mutect2, varscan2
- APC | c.5656G>A p.E1886K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.081); catalogued as rs587781400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLP1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs202136254; called by muse, mutect2, varscan2
- APOB | c.12230C>T p.A4077V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.846); catalogued as rs758921822, COSV51943308; called by muse, mutect2, varscan2
- APOB | c.9434C>A p.P3145H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51943163; called by muse, mutect2, varscan2
- APOBEC3G | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as rs535196357; called by mutect2, varscan2
- APOL4 | c.990G>A p.W330* (on ENST00000352371 / NM_145660.2; = p.W327* on NM_030643.4) | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as rs1445835266; called by muse, mutect2, varscan2
- AQR | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs752115325, COSV50047029; called by muse, mutect2, varscan2
- ARAP2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199740529, COSV58285033; called by muse, mutect2, varscan2
- ARFGEF3 | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99292603; called by muse, mutect2, varscan2
- ARHGAP10 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs370860233; called by muse, mutect2, varscan2
- ARHGAP17 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757526992, COSV51509775; called by muse, mutect2, varscan2
- ARHGAP29 | c.3424C>T p.R1142W | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as rs749933468; called by muse, mutect2, varscan2
- ARHGAP29 | c.2283G>T p.K761N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV99558677; called by muse, mutect2, varscan2
- ARHGAP30 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 39/125 reads (31%) | catalogued as COSV63515066; called by muse, mutect2, varscan2
- ARHGAP36 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370750175, COSV52271370; called by muse, mutect2, varscan2
- ARHGAP36 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV52263795; called by muse, mutect2, varscan2
- ARHGEF10 | c.235G>A p.A79T (on ENST00000398564; = p.A55T on NM_014629.4) | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.015); catalogued as rs138043149, COSV50686801; called by muse, mutect2, varscan2
- ARHGEF12 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1230537338, COSV100754963; called by muse, mutect2, varscan2
- ARHGEF15 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV62726575; called by muse, mutect2, varscan2
- ARHGEF17 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1285187269; called by muse, mutect2, varscan2
- ARHGEF17 | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as rs780905191, COSV55230187; called by muse, mutect2, varscan2
- ARHGEF2 | c.104G>T p.R35L (on ENST00000361247 / NM_001162383.2; = p.R8L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV58116154; called by muse, mutect2, varscan2
- ARHGEF25 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99677913; called by muse, varscan2
- ARHGEF26 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as rs575256445, COSV62846056; called by muse, mutect2, varscan2
- ARHGEF37 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs200439928, COSV100381830; called by mutect2, varscan2
- ARHGEF40 | c.3865C>T p.R1289C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432648515; called by muse, mutect2, varscan2
- ARHGEF9 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs1556300990; called by muse, mutect2, varscan2
- ARID4A | c.2641G>A p.V881I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs774970418; called by muse, mutect2, varscan2
- ARID5B | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269760932, COSV54414533; called by muse, mutect2, varscan2
- ARL13A | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs369115223, COSV65880286; called by muse, mutect2, varscan2
- ARL13B | c.955A>G p.N319D (on ENST00000394222 / NM_001174150.2; = p.N212D on NM_144996.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1236392985; called by muse, varscan2
- ARL16 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100230694; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs369432744, COSV100771865, COSV63438046; called by muse, mutect2, varscan2
- ARMH4 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs774365121; called by muse, mutect2, varscan2
- ARPC3 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs763570239; called by muse, mutect2, varscan2
- ARRB2 | c.54+2T>C p.X18_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV104369122; called by muse, mutect2, varscan2
- ARSF | c.1110A>C p.K370N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63840887; called by muse, mutect2, varscan2
- ARSJ | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766987490; called by muse, mutect2, varscan2
- ART4 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as rs775874295, COSV57452297, COSV99966843; called by muse, mutect2, varscan2
- ASB3 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.586); catalogued as COSV99711920; called by muse, mutect2, varscan2
- ASB4 | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1199376893; called by muse, mutect2, varscan2
- ASB5 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs773694713, COSV56669643, COSV56675393; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV60417431; called by muse, mutect2, varscan2
- ASL | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141216; called by muse, mutect2, varscan2
- ASMTL | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as rs761284758, COSV101187724; called by muse, mutect2, varscan2
- ASMTL | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751164203; called by muse, mutect2, varscan2
- ASNSD1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs1432628991, COSV53623902; called by muse, mutect2, varscan2
- ASPH | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.209); catalogued as rs758840739, COSV62858475; called by muse, mutect2, varscan2
- ASTN1 | c.2941-1G>T p.X981_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as COSV62494038; called by muse, mutect2, varscan2
- ASTN2 | c.3211C>T p.R1071W (on ENST00000313400 / NM_001365069.1; = p.R1020W on NM_014010.5) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374593775; called by muse, mutect2, varscan2
- ASXL1 | c.163T>A p.C55S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60122059; called by muse, mutect2, varscan2
- ASXL1 | c.4508C>T p.S1503L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV60104576; called by muse, mutect2, varscan2
- ASXL2 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs866322431, COSV55467876; called by muse, mutect2, varscan2
- ATAD2 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1270279267, COSV54880131, COSV54880435; called by muse, mutect2, varscan2
- ATAD2 | c.321G>A p.R107= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as COSV54884539; called by muse, mutect2, varscan2
- ATF7-NPFF | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs771626678, COSV57200660; called by muse, mutect2, varscan2
- ATG16L1 | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100731202; called by muse, mutect2, varscan2
- ATG3 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1204944842, COSV51925872; called by muse, mutect2, varscan2
- ATG4D | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs757360354; called by muse, mutect2, varscan2
- ATL1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs149901427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATL3 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60295134; called by muse, varscan2
- ATP10A | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as rs17854738, COSV100791103, COSV63515206; called by muse, mutect2, varscan2
- ATP10B | c.2743A>G p.T915A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770669534; called by muse, mutect2, varscan2
- ATP10D | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs201010617, COSV56709867; called by muse, mutect2, varscan2
- ATP11A | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs376199880; called by muse, mutect2, varscan2
- ATP12A | c.2777G>T p.R926M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99516758; called by muse, mutect2, varscan2
- ATP13A4 | c.2302A>G p.M768V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1245445337; called by muse, mutect2, varscan2
- ATP13A4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1388188111; called by muse, mutect2, varscan2
- ATP13A5 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60866948; called by muse, mutect2, varscan2
- ATP1B3 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.404); catalogued as rs777792091, COSV53951830; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP2B3 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as rs1557009377; called by muse, mutect2, varscan2
- ATP2B3 | c.3299G>A p.G1100D | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99686182; called by muse, mutect2, varscan2
- ATP2C1 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60760172; called by muse, mutect2, varscan2
- ATP2C2 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs768610905, COSV52294767, COSV52299784; called by muse, mutect2, varscan2
- ATP5MPL | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99744022; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2219G>A p.R740Q (on ENST00000343619 / NM_001378531.1; = p.R734Q on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567871600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1A | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs922143048, COSV56360731, COSV56364398; called by muse, mutect2, varscan2
- ATP6V1A | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1267940741; called by muse, mutect2
- ATP6V1H | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV100778617; called by muse, varscan2
- ATP8A2 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54960468; called by muse, mutect2, varscan2
- ATP8A2 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs373188486; called by muse, mutect2, varscan2
- ATP8B4 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs760720943, COSV52708861; called by muse, mutect2, varscan2
- ATP8B4 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1055481273; called by muse, mutect2, varscan2
- ATP9B | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); catalogued as rs367655880; called by muse, mutect2, varscan2
- ATR | c.5440dup p.R1814Kfs*8 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs1268253442; called by mutect2, varscan2
- ATRX | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100969550; called by muse, mutect2, varscan2
- ATXN2 | c.1345G>A p.E449K (on ENST00000550104; = p.E289K on NM_002973.4) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66483025; called by muse, mutect2, varscan2
- AURKA | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV57167417; called by muse, mutect2, varscan2
- AURKC | c.625G>T p.E209* (on ENST00000302804 / NM_001015878.2; = p.E175* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as rs1192298496, COSV100248917; called by muse, mutect2, varscan2
- B3GALT4 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV65851218; called by muse, varscan2
- B3GNT2 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs980888736; called by muse, mutect2, varscan2
- B4GALT4 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as rs1184427718, COSV63296567; called by muse, mutect2, varscan2
- BABAM1 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs765555081, COSV53106564; called by muse, varscan2
- BACE1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs371130142; called by muse, varscan2
- BAMBI | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs369743386; called by muse, mutect2, varscan2
- BAZ1A | c.2796G>T p.Q932H | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.758); catalogued as rs770503386; called by muse, mutect2, varscan2
- BAZ1B | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV59988555; called by muse, mutect2, varscan2
- BAZ2B | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58604097; called by muse, mutect2, varscan2
- BBS10 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV53879714; called by muse, mutect2, varscan2
- BBS12 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760420127, COSV58562020; called by muse, mutect2, varscan2
- BBS9 | c.1433-1G>A p.X478_splice | Splice Site (SNP) | VAF 25/60 reads (42%) | catalogued as COSV99626651; called by muse, mutect2, varscan2
- BBX | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749597573; called by muse, mutect2, varscan2
- BCAN | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs777357775; called by muse, mutect2, varscan2
- BCAP31 | c.342-1G>T p.X114_splice | Splice Site (SNP) | VAF 17/37 reads (46%) | catalogued as rs879971700; called by muse, mutect2, varscan2
- BCAR1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748548124, COSV50780951; called by muse, mutect2, varscan2
- BCAS3 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as rs776214324, COSV101176582; called by muse, mutect2, varscan2
- BCL6B | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1197425210; called by muse, mutect2, varscan2
- BCL9 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782700818, COSV52342778; called by muse, mutect2, varscan2
- BCLAF1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100786666; called by muse, mutect2, varscan2
- BCO1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); catalogued as rs764080372, COSV99257860; called by muse, mutect2, varscan2
- BCOR | c.3789G>T p.E1263D (on ENST00000378444 / NM_001123385.2; = p.E1229D on NM_017745.6) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV60721479; called by muse, mutect2, varscan2
- BDH2 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56478116; called by muse, mutect2, varscan2
- BDNF | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as rs267602837; called by muse, mutect2, varscan2
- BEND2 | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs867284454; called by muse, mutect2, varscan2
- BEND3 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); catalogued as rs782298498, COSV64682197; called by muse, mutect2, varscan2
- BICRAL | c.2885C>T p.S962L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.093); catalogued as rs769129854; called by muse, mutect2, varscan2
- BIK | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.486); catalogued as COSV99330486; called by muse, mutect2, varscan2
- BIRC3 | c.1666A>G p.T556A | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV54819412; called by muse, mutect2, varscan2
- BIRC6 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV70196917; called by muse, mutect2, varscan2
- BIRC6 | c.12857A>G p.Q4286R | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1365582441, COSV70197027; called by muse, mutect2, varscan2
- BIRC6 | c.14195G>A p.R4732Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs772472693, COSV70205647; called by mutect2, varscan2
- BIVM-ERCC5 | c.3524C>T p.A1175V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs376753356; called by muse, mutect2, varscan2
- BLID | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV101601729; called by muse, mutect2, varscan2
- BMP10 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1372582750, COSV99770310; called by muse, mutect2, varscan2
- BMPER | c.1903T>C p.Y635H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256276005; called by muse, mutect2, varscan2
- BMPR1A | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766908700, CM090206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMS1 | c.3184C>T p.R1062* | Nonsense Mutation (SNP) | VAF 117/266 reads (44%) | catalogued as rs759014042, COSV65733123; called by muse, mutect2, varscan2
- BMX | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 37/104 reads (36%) | catalogued as COSV59592185; called by muse, mutect2, varscan2
- BMX | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758831876, COSV100564460; called by muse, mutect2, varscan2
- BNC1 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766072426, COSV61757106, COSV61758012; called by muse, mutect2, varscan2
- BNC1 | c.910T>C p.C304R | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.107); catalogued as rs772310670; called by muse, mutect2, varscan2
- BNC2 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 48/110 reads (44%) | catalogued as COSV66157290; called by muse, mutect2, varscan2
- BNIP5 | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1209449496, COSV71325400; called by muse, mutect2, varscan2
- BPGM | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1206399907, COSV100790224; called by muse, varscan2
- BPTF | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs759643114, COSV58834684; called by muse, mutect2, varscan2
- BRD8 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs372286313; called by muse, mutect2, varscan2
- BRINP3 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs751255099, COSV66528308; called by muse, mutect2, varscan2
- BRINP3 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs757438144, COSV100819444, COSV66529448; called by muse, mutect2, varscan2
- BRINP3 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs762902347; called by muse, mutect2, varscan2
- BRWD3 | c.5180G>A p.R1727H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.382); catalogued as rs144015236, COSV100955915; called by muse, mutect2, varscan2
- BRWD3 | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV64746283; called by muse, mutect2, varscan2
- BSDC1 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756871320, COSV61983324; called by muse, mutect2, varscan2
- BTAF1 | c.5089C>T p.P1697S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56429875; called by muse, mutect2, varscan2
- BTBD6 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1393102254; called by muse, mutect2, varscan2
- BTBD9 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs760514311; called by muse, mutect2, varscan2
- BTN2A1 | c.1120T>C p.C374R | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269809105; called by muse, mutect2, varscan2
- BTNL8 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs748602705, COSV51460359; called by muse, mutect2, varscan2
- BUD13 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as rs1335672884, COSV52768031; called by muse, mutect2, varscan2
- C10orf90 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs765589979, COSV52960031; called by muse, mutect2, varscan2
- C10orf90 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1422755265; called by muse, mutect2, varscan2
- C12orf40 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100210416; called by muse, mutect2, varscan2
- C16orf89 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs1366296763, COSV60125129; called by muse, mutect2, varscan2
- C17orf58 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782074871; called by muse, mutect2, varscan2
- C1QTNF1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs766775216; called by muse, varscan2
- C1QTNF3 | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99039625; called by muse, mutect2, varscan2
- C1QTNF7 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs763723180; called by muse, mutect2, varscan2
- C1QTNF7 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs776448155, COSV54856211; called by muse, mutect2, varscan2
- C1QTNF9B | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1270822220; called by muse, mutect2
- C1orf112 | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750350439; called by muse, mutect2, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 41/120 reads (34%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2, varscan2
- C1orf94 | c.853G>T p.G285W (on ENST00000488417 / NM_001134734.2; = p.G95W on NM_032884.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100974994; called by muse, mutect2, varscan2
- C20orf194 | c.2845C>T p.R949* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as rs758002344; called by muse, mutect2, varscan2
- C20orf194 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759083731; called by muse, mutect2, varscan2
- C2CD5 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV61723085; called by muse, mutect2, varscan2
- C2orf16 | c.4569G>T p.K1523N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.25); catalogued as COSV99051898; called by muse, mutect2
- C2orf78 | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV68516290; called by muse, mutect2, varscan2
- C8orf76 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541928498; called by muse, mutect2, varscan2
- C9orf131 | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV100397979; called by muse, mutect2, varscan2
- C9orf85 | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV58255509; called by muse, mutect2, varscan2
- CA10 | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.269); catalogued as COSV53349220; called by muse, mutect2, varscan2
- CACNA1A | c.5051G>A p.R1684H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64198843; called by muse, mutect2, varscan2
- CACNA1E | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100703875; called by muse, mutect2, varscan2
- CACNA2D1 | c.2369C>T p.S790L (on ENST00000356253 / NM_001366867.1; = p.S778L on NM_000722.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as rs202108848, COSV62373773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB1 | c.629-1G>T p.X210_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV59998420; called by muse, mutect2, varscan2
- CACNB3 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776012207; called by mutect2, varscan2
- CACNB4 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs563023146, COSV52395401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG1 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1425846610; called by muse, mutect2, varscan2
- CAD | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs761369810, COSV99254420; called by muse, mutect2, varscan2
- CADPS2 | c.1931C>A p.A644D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.924); catalogued as COSV57389208; called by muse, mutect2, varscan2
- CALN1 | c.22G>A p.A8T (on ENST00000329008 / NM_001017440.3; = p.A50T on NM_031468.4) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs767526121, COSV61141568; called by muse, mutect2, varscan2
- CAMK2A | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs200216623; called by muse, mutect2, varscan2
- CAMK2G | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as CM1211472; called by muse, mutect2, varscan2
- CAND1 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV101607331; called by muse, mutect2, varscan2
- CAPN5 | c.1789A>G p.T597A (on ENST00000456580; = p.T557A on NM_004055.5) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs1432315849; called by muse, mutect2
- CAPN7 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as rs755151623, COSV53777783; called by muse, mutect2, varscan2
- CAPRIN2 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.294); catalogued as rs371879635; called by muse, mutect2, varscan2
- CARD6 | c.50dup p.L18Vfs*3 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs767757618; called by mutect2, pindel, varscan2
- CARMIL1 | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs377729426; called by muse, mutect2, varscan2
- CARMIL2 | c.3635G>A p.R1212Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs769495465; called by muse, mutect2, varscan2
- CARMIL3 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs368911954; called by muse, varscan2
- CARNMT1 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV65193870; called by muse, mutect2, varscan2
- CARTPT | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99703903; called by muse, mutect2, varscan2
- CASK | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59372296; called by muse, mutect2
- CASP3 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs567223280, COSV57725046; called by muse, mutect2, varscan2
- CASP8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV51847255, COSV51849187; called by muse, mutect2, varscan2
- CASP8 | c.1313A>C p.D438A (on ENST00000432109 / NM_033355.3; = p.D455A on NM_001228.4) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99629668, COSV99630738; called by muse, mutect2, varscan2
- CASP8AP2 | c.758G>T p.S253I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV99387467; called by muse, mutect2, varscan2
- CATSPERB | c.2606A>G p.Y869C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56433022; called by muse, mutect2, varscan2
- CATSPERB | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV56425882; called by muse, mutect2, varscan2
- CBL | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755244263, COSV50633583; called by muse, mutect2, varscan2
- CBLB | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); catalogued as rs777823614; called by muse, mutect2, varscan2
- CBLB | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs774346321, COSV99914042; called by muse, mutect2, varscan2
- CBWD2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 151/417 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1184992164, COSV52076388; called by muse, mutect2, varscan2
- CCBE1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761881641, COSV67950286, COSV67951393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC102B | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100103098; called by muse, varscan2
- CCDC102B | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs369503833; called by muse, varscan2
- CCDC102B | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749317561; called by muse, mutect2, varscan2
- CCDC106 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs760403510, COSV54402624; called by muse, mutect2, varscan2
- CCDC136 | c.3455C>T p.T1152M | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs750393533; called by muse, mutect2, varscan2
- CCDC141 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1429178522, COSV55373924; called by muse, mutect2, varscan2
- CCDC150 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as rs1355483344, COSV55876116; called by muse, mutect2, varscan2
- CCDC151 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs755958822; called by mutect2, varscan2
- CCDC171 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs775878363; called by muse, mutect2, varscan2
- CCDC171 | c.3512A>G p.N1171S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as rs367952979; called by muse, mutect2, varscan2
- CCDC186 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs758664195, COSV65161010; called by muse, mutect2, varscan2
- CCDC34 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs371291657; called by muse, mutect2, varscan2
- CCDC42 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs866068531; called by muse, mutect2, varscan2
- CCDC66 | c.2057G>T p.R686I (on ENST00000394672 / NM_001353147.1; = p.R652I on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs771523631; called by muse, mutect2, varscan2
- CCDC7 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV56552738; called by muse, mutect2, varscan2
- CCDC86 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753482209, COSV57124852; called by muse, varscan2
- CCDC88B | c.3857G>A p.R1286H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199590555, COSV57268416; called by muse, mutect2, varscan2
- CCDC90B | c.711T>G p.A237= | Splice Region (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99475368; called by muse, mutect2
- CCL3 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1251992195; called by muse, mutect2
- CCN6 | c.668G>A p.C223Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57890335; called by muse, mutect2, varscan2
- CCNB1IP1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.569); catalogued as COSV62302563; called by muse, mutect2, varscan2
- CCNG1 | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV61652161; called by muse, mutect2, varscan2
- CCNY | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1367498165; called by muse, mutect2
- CCNY | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776947431; called by muse, mutect2, varscan2
- CCNY | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771715363, COSV55191875; called by muse, varscan2
- CCP110 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762998961, COSV66816643; called by muse, mutect2, varscan2
- CCPG1 | c.1988A>G p.Y663C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051034818; called by muse, mutect2, varscan2
- CCPG1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1485834962, COSV51241189; called by muse, mutect2
- CCR5 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.062); catalogued as rs959967668, COSV52751614; called by muse, varscan2
- CCSER1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs748810862, COSV61420008, COSV61444965; called by muse, mutect2
- CCT5 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs375499316; called by muse, mutect2, varscan2
- CD101 | c.2618A>G p.Y873C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1392749578; called by muse, mutect2, varscan2
- CD109 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs761682929; called by muse, mutect2, varscan2
- CD109 | c.2662A>G p.T888A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs754326353; called by muse, mutect2, varscan2
- CD1B | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV63805052; called by muse, mutect2, varscan2
- CD1D | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs755775062, COSV100939663; called by muse, varscan2
- CD200 | c.376C>T p.L126F (on ENST00000473539 / NM_001004196.3; = p.L101F on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs1387422366; called by muse, mutect2, varscan2
- CD200R1 | c.170C>A p.A57D (on ENST00000471858 / NM_170780.3; = p.A80D on NM_138806.4) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs758670426; called by muse, varscan2
- CD207 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs957871402; called by muse, mutect2, varscan2
- CD274 | c.601A>C p.T201P | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV101056164; called by muse, mutect2, varscan2
- CD3E | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs563868055, COSV62346096; called by muse, mutect2, varscan2
- CD44 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV53533251; called by muse, mutect2
- CD47 | c.459A>G p.I153M | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100790094; called by muse, mutect2
- CD53 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs531836002, COSV54761209; called by muse, mutect2, varscan2
- CD8A | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs751505456; called by muse, mutect2, varscan2
- CD96 | c.1720G>A p.E574K (on ENST00000283285 / NM_198196.3; = p.E558K on NM_005816.5) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs201121432, COSV51912523, COSV51916031; called by muse, mutect2, varscan2
- CDC14B | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753779684; called by muse, mutect2, varscan2
- CDC42BPA | c.2434G>T p.E812* | Nonsense Mutation (SNP) | VAF 53/143 reads (37%) | catalogued as COSV62002036; called by muse, mutect2, varscan2
- CDC42BPA | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV62024076; called by muse, mutect2, varscan2
- CDC42BPA | c.293del p.N98Mfs*8 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | catalogued as rs1558779048; called by mutect2, pindel, varscan2
- CDC42EP3 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99767745; called by muse, mutect2, varscan2
- CDC73 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV100814094; called by muse, mutect2, varscan2
- CDH10 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV52584202; called by muse, varscan2
- CDH12 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 60/185 reads (32%) | catalogued as COSV66396285, COSV66415403; called by muse, mutect2, varscan2
- CDH17 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as rs757379385; called by muse, mutect2, varscan2
- CDH18 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs771062780, COSV56912409, COSV56939656; called by muse, varscan2
- CDH19 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50981032; called by muse, mutect2, varscan2
- CDH2 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52281877; called by muse, mutect2
- CDH2 | c.2165C>T p.T722I | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as rs781525713; called by muse, mutect2, varscan2
- CDH2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52286358; called by muse, mutect2, varscan2
- CDH22 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs371935785; called by muse, mutect2, varscan2
- CDH23 | c.4274C>T p.A1425V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs753568239; called by muse, varscan2
- CDH24 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.91); catalogued as rs147450903; called by muse, varscan2
- CDH3 | c.503T>C p.L168S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.196); catalogued as CM032866; called by muse, mutect2, varscan2
- CDH5 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs147993570; called by muse, varscan2
- CDH9 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50278301; called by muse, mutect2, varscan2
- CDHR5 | c.1631C>T p.P544L (on ENST00000358353 / NM_001171968.2; = p.P550L on NM_021924.5) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs148641095, COSV100363692; called by muse, mutect2, varscan2
- CDK13 | c.2460G>T p.Q820H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476141; called by muse, mutect2, varscan2
- CDK13 | c.2872C>T p.R958* | Nonsense Mutation (SNP) | VAF 42/133 reads (32%) | catalogued as COSV51703472; called by muse, mutect2, varscan2
- CDK4 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1555201372, COSV56986445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP2 | c.934A>G p.N312D | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1213885447; called by muse, mutect2, varscan2
- CDK5RAP2 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764452414; called by muse, mutect2, varscan2
- CDKL5 | c.2668C>T p.R890W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs1354788122, COSV66112857; called by muse, mutect2, varscan2
- CDNF | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as rs376250440; called by muse, mutect2, varscan2
- CDRT1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs926444172; called by muse, mutect2
- CDS2 | c.291+1G>A p.X97_splice | Splice Site (SNP) | VAF 30/99 reads (30%) | catalogued as COSV66896464; called by muse, mutect2, varscan2
- CDYL | c.710C>T p.A237V (on ENST00000328908 / NM_001368125.1; = p.A183V on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs548377074, COSV100190127; called by muse, varscan2
- CDYL | c.1381G>A p.D461N (on ENST00000328908 / NM_001368125.1; = p.D407N on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1398064326; called by muse, mutect2, varscan2
- CEACAM18 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs772876360, COSV67282317, COSV67283582; called by muse, mutect2, varscan2
- CEACAM20 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.625); catalogued as rs745625554, COSV57601380; called by muse, mutect2, varscan2
- CEACAM8 | c.685G>T p.V229F | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.199); catalogued as COSV54990055; called by muse, mutect2, varscan2
- CEBPZ | c.2276T>G p.F759C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1213741574; called by muse, mutect2, varscan2
- CELSR1 | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269686459; called by muse, varscan2
- CEMIP | c.3325G>A p.V1109I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs751807711, COSV54999593; called by muse, mutect2, varscan2
- CEMIP2 | c.3197A>C p.N1066T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV65485046; called by muse, mutect2, varscan2
- CEMIP2 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs746389869, COSV65488164; called by muse, mutect2, varscan2
- CEMIP2 | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100987504; called by muse, mutect2, varscan2
- CENPC | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs989407976, COSV99893560; called by muse, mutect2, varscan2
- CENPE | c.7247A>G p.D2416G | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54380370; called by muse, mutect2, varscan2
- CENPE | c.2854A>G p.I952V | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs1181616793; called by muse, mutect2, varscan2
- CENPF | c.7220G>A p.R2407Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs764028137; called by muse, mutect2, varscan2
- CEP128 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1317178446; called by muse, mutect2, varscan2
- CEP152 | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs139994108; called by muse, mutect2, varscan2
- CEP170 | c.4069C>T p.R1357C | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60506901; called by muse, mutect2, varscan2
- CEP192 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752331027, COSV58064729; called by muse, mutect2, varscan2
- CEP44 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.682); catalogued as rs1443261688; called by muse, mutect2, varscan2
- CEP63 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs202055421, COSV59675935; called by muse, mutect2, varscan2
- CEP70 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs142393409; called by muse, mutect2, varscan2
- CEP85 | c.2127C>T p.H709= | Splice Region (SNP) | VAF 14/27 reads (52%) | catalogued as rs750878191; called by muse, varscan2
- CERS2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54982769; called by muse, mutect2, varscan2
- CERS3 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758046951, COSV52568339; called by muse, mutect2, varscan2
- CERS5 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1272644311; called by muse, varscan2
- CETN1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as rs747779128, COSV59121371; called by muse, varscan2
- CETN1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs760929013, COSV59121106, COSV59121251; called by muse, varscan2
- CFAP54 | c.5672G>A p.R1891Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as rs367592020; called by muse, mutect2, varscan2
- CFAP57 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs1190624609; called by muse, mutect2, varscan2
- CFAP58 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs746292556, COSV57211513; called by muse, mutect2
- CFAP58 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV63832669; called by muse, mutect2, varscan2
- CFAP61 | c.3374A>G p.N1125S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs749731806; called by muse, mutect2, varscan2
- CFAP69 | c.1872dup p.F625Ifs*3 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | catalogued as rs763364101; called by mutect2, varscan2
- CFAP91 | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1224656418; called by muse, mutect2, varscan2
- CFC1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs773287120, COSV52090573, COSV99383542; called by mutect2, varscan2
- CFHR3 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs376975192; called by muse, mutect2, varscan2
- CHAMP1 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782149634, COSV63522582; called by muse, mutect2, varscan2
- CHCHD4 | c.32G>A p.R11Q (on ENST00000396914 / NM_001098502.2; = p.R24Q on NM_144636.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs755009391, COSV55499938; called by muse, mutect2, varscan2
- CHCHD6 | c.506T>C p.M169T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.199); catalogued as rs1214527617; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD1 | c.2718+2T>C p.X906_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV104370010; called by muse, mutect2, varscan2
- CHD3 | c.4030C>T p.R1344C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100390604; called by muse, mutect2, varscan2
- CHD8 | c.856C>T p.R286C (on ENST00000646647 / NM_001170629.2; = p.R7C on NM_020920.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs762427755, CM164644; called by muse, mutect2, varscan2
- CHD9 | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1490981223, COSV68297628; called by muse, mutect2, varscan2
- CHEK1 | c.783A>C p.K261N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as rs1275492676; called by mutect2, varscan2
- CHGA | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs1233805788; called by muse, mutect2, varscan2
- CHGB | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs749077565, COSV66761544; called by muse, varscan2
- CHI3L1 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200974099; called by muse, mutect2, varscan2
- CHI3L2 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.08); catalogued as rs1557708958; called by muse, mutect2, varscan2
- CHKA | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99694070, COSV99694128; called by muse, mutect2, varscan2
- CHM | c.1757A>G p.N586S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV63304834; called by muse, mutect2, varscan2
- CHM | c.703-1G>T p.X235_splice | Splice Site (SNP) | VAF 30/91 reads (33%) | catalogued as CS076606, CS147372; called by muse, mutect2, varscan2
- CHRD | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV52607749; called by muse, mutect2, varscan2
- CHRD | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52612844; called by muse, mutect2, varscan2
- CHRM2 | c.554C>A p.A185D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV57776844; called by muse, mutect2, varscan2
- CHRNA3 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100468475; called by muse, mutect2, varscan2
- CHRNA4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1064795157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNB2 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs749633440; called by muse, mutect2, varscan2
- CHST2 | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as COSV58885608; called by muse, mutect2, varscan2
- CHST8 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773533591, COSV52862808; called by mutect2, varscan2
- CIAO3 | c.301A>G p.N101D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs570373646; called by muse, mutect2, varscan2
- CIP2A | c.2128C>A p.L710I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1052739330; called by muse, mutect2, varscan2
- CLASP2 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56288896; called by muse, mutect2, varscan2
- CLBA1 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV66348388; called by muse, mutect2, varscan2
- CLCA2 | c.1713+1G>A p.X571_splice | Splice Site (SNP) | VAF 24/91 reads (26%) | catalogued as rs1189514793; called by muse, mutect2, varscan2
- CLCN1 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.478); catalogued as rs749846585; called by muse, mutect2, varscan2
- CLCN4 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs752631287, COSV66465168; ClinVar: uncertain significance; called by muse, varscan2
- CLCN6 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100411827; called by muse, mutect2, varscan2
- CLCN7 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs553977226; ClinVar: uncertain significance; called by muse, varscan2
- CLDN1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs754012333; called by mutect2, varscan2
- CLEC1B | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237872141, COSV53725393, COSV53726050; called by muse, varscan2
- CLEC2B | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57310923; called by muse, mutect2, varscan2
- CLEC2B | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99947039; called by muse, mutect2, varscan2
- CLEC7A | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758262143; called by muse, mutect2, varscan2
- CLK2 | c.673C>T p.L225F (on ENST00000368361 / NM_001294339.2; = p.L224F on NM_003993.4) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as rs753594210; called by muse, mutect2, varscan2
- CLK2 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs749596664; called by muse, mutect2, varscan2
- CLSTN2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756136789, COSV71723435; called by muse, mutect2, varscan2
- CLU | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs761369634, COSV57066672; called by muse, mutect2, varscan2
- CMAS | c.405G>A p.E135= | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99982669; called by muse, varscan2
- CMYA5 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs756218416; called by muse, mutect2, varscan2
- CMYA5 | c.4565T>C p.V1522A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs746462149, COSV71404530; called by mutect2, varscan2
- CMYA5 | c.7439T>C p.V2480A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs569914800; called by mutect2, varscan2
- CNGA1 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.217); catalogued as rs768687517; called by mutect2, varscan2
- CNGA2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs755262067; called by muse, mutect2, varscan2
- CNGB1 | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs1034133341, COSV51907408; called by muse, mutect2, varscan2
- CNGB3 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs376711003, COSV60692258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNKSR2 | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV99669128; called by muse, mutect2, varscan2
- CNKSR2 | c.1064del p.P355Lfs*104 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as COSV54248911; called by mutect2, pindel, varscan2
- CNKSR2 | c.1846G>T p.G616* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as COSV99667238; called by muse, mutect2, varscan2
- CNNM1 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs756965194, COSV63200613; called by muse, mutect2, varscan2
- CNOT1 | c.5363T>C p.I1788T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV99799281; called by muse, mutect2, varscan2
- CNOT1 | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs908447924, COSV57767368; called by muse, mutect2, varscan2
- CNOT10 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.32); catalogued as rs770500134, COSV59391357; called by muse, mutect2, varscan2
- CNOT4 | c.1657C>A p.P553T (on ENST00000315544 / NM_001190848.1; = p.P550T on NM_001008225.2) | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1444205963; called by muse, mutect2, varscan2
- CNOT4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59655715; called by muse, mutect2, varscan2
- CNP | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as rs1283506174; called by muse, mutect2, varscan2
- CNRIP1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139324099; called by muse, mutect2, varscan2
- CNST | c.617-1G>C p.X206_splice | Splice Site (SNP) | VAF 24/46 reads (52%) | catalogued as COSV63620195; called by muse, mutect2, varscan2
- CNTN1 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs775098655; called by muse, mutect2, varscan2
- CNTN1 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61639322; called by muse, varscan2
- CNTN4 | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as rs759065205, COSV61873523; called by muse, mutect2, varscan2
- CNTN6 | c.2495C>A p.T832N | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.998); catalogued as rs762757510; called by muse, mutect2, varscan2
- CNTNAP4 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs771102336; called by muse, mutect2, varscan2
- CNTRL | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.1); catalogued as COSV53042628, COSV53043540; called by muse, mutect2, varscan2
- CNTRL | c.4702C>T p.L1568F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs867190019; called by muse, mutect2, varscan2
- CNTROB | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.116); catalogued as rs753613469; called by muse, mutect2, varscan2
- COG1 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs774479733, COSV55431495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COG7 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as rs754431741, COSV56150331; called by muse, mutect2, varscan2
- COL11A2 | c.1867C>T p.P623S (on ENST00000341947 / NM_080680.3; = p.P516S on NM_080679.2) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.734); catalogued as rs553386615; called by muse, mutect2, varscan2
- COL15A1 | c.4064C>T p.P1355L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as rs143545156; called by muse, mutect2, varscan2
- COL17A1 | c.4303G>A p.A1435T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1313908055; called by muse, mutect2, varscan2
- COL1A1 | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as rs867287942; called by muse, mutect2, varscan2
- COL22A1 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57344495; called by muse, varscan2
- COL25A1 | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV67650938; called by muse, mutect2, varscan2
- COL27A1 | c.2124+2T>C p.X708_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as rs760476125, COSV61924268; called by muse, mutect2, varscan2
- COL28A1 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs141928495, COSV68081743; called by mutect2, varscan2
- COL4A6 | c.3215G>A p.G1072D | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358237829; called by muse, mutect2, varscan2
- COL5A2 | c.3053A>C p.K1018T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99058959; called by muse, mutect2, varscan2
- COL6A3 | c.4900G>A p.E1634K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs1270637416; called by muse, mutect2, varscan2
- COLGALT1 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs745919348; called by muse, mutect2, varscan2
- COMP | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs745399869, COSV55874206; called by muse, mutect2, varscan2
- COPB2 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs749130594, COSV60351227; called by muse, mutect2, varscan2
- CORIN | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs757886805, COSV56685795; called by muse, mutect2, varscan2
- COX10 | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1023600507; called by muse, mutect2, varscan2
- CP | c.1454A>G p.N485S | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs779758482; called by muse, mutect2, varscan2
- CP | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs1286440771, COSV52829767; called by muse, mutect2, varscan2
- CPA3 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56046187; called by muse, mutect2, varscan2
- CPA4 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99744736; called by muse, mutect2, varscan2
- CPE | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as COSV101291691; called by muse, mutect2, varscan2
- CPEB1 | c.1274T>G p.V425G (on ENST00000617958; = p.V360G on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs755502093; called by muse, mutect2, varscan2
- CPEB3 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV56457136; called by muse, mutect2
- CPED1 | c.1115T>C p.M372T | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs750348141; called by muse, mutect2, varscan2
- CPED1 | c.2045G>A p.G682D | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV100120893; called by muse, mutect2, varscan2
- CPLX2 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs757770941, COSV100853112; called by muse, mutect2, varscan2
- CPNE4 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.536); catalogued as rs201950887; called by muse, varscan2
- CPNE5 | c.1447A>G p.M483V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs374662379; called by mutect2, varscan2
- CPNE8 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1015325273; called by muse, mutect2, varscan2
- CPSF1 | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1554865014; called by muse, mutect2, varscan2
- CPT1C | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749349711, COSV54917945; called by muse, mutect2, varscan2
- CPXCR1 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs151082010; called by muse, mutect2, varscan2
- CPXM1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs201256870, COSV66045253; called by muse, mutect2, varscan2
- CR1 | c.4465C>T p.R1489* | Nonsense Mutation (SNP) | VAF 92/217 reads (42%) | catalogued as rs778591697, COSV65456307; called by muse, mutect2, varscan2
- CR1L | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.348); catalogued as rs1172263771, COSV54322718; called by muse, varscan2
- CR2 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100889551; called by muse, mutect2, varscan2
- CR2 | c.1423G>T p.G475* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV65508303; called by muse, mutect2, varscan2
- CRADD | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs534423825, COSV60554940; called by muse, mutect2, varscan2
- CRBN | c.1241T>G p.F414C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99214236; called by muse, mutect2, varscan2
- CREB3L3 | c.717C>T p.Y239= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as rs770536224; called by muse, varscan2
- CREB5 | c.76C>T p.R26C (on ENST00000357727 / NM_182898.4; = p.R19C on NM_004904.3) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs754986749; called by muse, varscan2
- CREBBP | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as rs768030911, COSV52123741; called by muse, varscan2
- CRIM1 | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs200582106, COSV54860150; called by muse, varscan2
- CRISPLD2 | c.1129A>G p.S377G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs759169076; called by muse, mutect2, varscan2
- CRMP1 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs370480340; called by muse, mutect2, varscan2
- CRYBA4 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs200572268; called by muse, mutect2, varscan2
- CRYBG2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs373673197; called by muse, mutect2, varscan2
- CRYBG3 | c.7394C>T p.P2465L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1476200734, COSV99477137; called by muse, varscan2
- CRYBG3 | c.7952C>T p.S2651L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759694546, COSV99476956; called by muse, mutect2, varscan2
- CSF1R | c.1892T>C p.M631T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs766891047; called by muse, mutect2, varscan2
- CSF2RB | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs146404001, COSV53257443; called by muse, mutect2, varscan2
- CSF3R | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs372972496; called by muse, mutect2, varscan2
- CSF3R | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs1169509563; called by muse, mutect2, varscan2
- CSMD1 | c.4573T>C p.S1525P (on ENST00000520002; = p.S1524P on NM_033225.6) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs770240879; called by mutect2, varscan2
- CSMD1 | c.3002C>T p.T1001I (on ENST00000520002; = p.T1000I on NM_033225.6) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59294813; called by muse, mutect2, varscan2
- CSMD1 | c.1604C>T p.A535V (on ENST00000520002; = p.A534V on NM_033225.6) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs746714804, COSV59306301; called by muse, mutect2, varscan2
- CSMD2 | c.6947A>G p.D2316G | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1557579687, COSV99587977; called by muse, mutect2, varscan2
- CSMD2 | c.4661C>T p.P1554L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.942); catalogued as rs748157929, COSV53935107; called by muse, mutect2, varscan2
- CSMD2 | c.3060C>A p.F1020L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325773140, COSV99587545; called by muse, mutect2, varscan2
- CSMD3 | c.8542C>T p.R2848* (on ENST00000297405 / NM_001363185.1; = p.R2679* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV52187779; called by muse, mutect2, varscan2
- CSMD3 | c.1708A>G p.S570G (on ENST00000297405 / NM_001363185.1; = p.S466G on NM_052900.3) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV52260629; called by muse, varscan2
- CSNK1G1 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV57306614; called by muse, mutect2, varscan2
- CSNK1G1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV57307102, COSV57312016; called by muse, mutect2, varscan2
- CSPG4 | c.2716C>T p.L906F | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs768352707, COSV57898272; called by muse, mutect2, varscan2
- CST5 | c.234C>T p.I78= | Splice Region (SNP) | VAF 8/35 reads (23%) | catalogued as rs913615087, COSV59014341; called by muse, varscan2
- CST9 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as rs866932350; called by muse, mutect2, varscan2
- CTAGE1 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1335679810; called by muse, mutect2
- CTAGE6 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.06); catalogued as COSV69918636; called by mutect2, varscan2
- CTC1 | c.3256G>A p.V1086M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1347868680; called by muse, mutect2, varscan2
- CTCF | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1486997074, COSV99866509; called by muse, mutect2, varscan2
- CTDSP2 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs772434435, COSV66079929; called by muse, mutect2, varscan2
- CTNNA1 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as rs371052704, COSV57076227; called by muse, mutect2, varscan2
- CTNNA2 | c.1811T>C p.F604S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.165); catalogued as COSV58190362; called by muse, mutect2, varscan2
- CTNNA3 | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65555168, COSV65621489; called by muse, mutect2
- CTNNAL1 | c.2163G>A p.W721* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as COSV57704800; called by muse, mutect2, varscan2
- CTNNB1 | c.2319G>T p.Q773H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs1340254110; called by muse, mutect2, varscan2
- CTNNBL1 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 44/120 reads (37%) | catalogued as COSV63747260; called by muse, mutect2, varscan2
- CTNND1 | c.2271G>T p.K757N (on ENST00000399050 / NM_001085458.2; = p.K751N on NM_001331.3) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs894225352, COSV62382086; called by muse, mutect2, varscan2
- CTNND2 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs867204139, COSV58867189; called by muse, mutect2, varscan2
- CTPS2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs946825746; called by muse, mutect2, varscan2
- CTPS2 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63722086; called by muse, mutect2, varscan2
- CTTNBP2 | c.899C>A p.T300N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV99355237; called by muse, mutect2, varscan2
- CTXN3 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs777369803; called by mutect2, varscan2
- CUBN | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs778751361; called by muse, mutect2, varscan2
- CUL2 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs754853022; called by muse, varscan2
- CUL2 | c.1002+1G>A p.X334_splice | Splice Site (SNP) | VAF 27/55 reads (49%) | catalogued as COSV66078723; called by muse, mutect2, varscan2
- CUL3 | c.547A>C p.I183L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV52362938, COSV52365424; called by muse, mutect2, varscan2
- CUL5 | c.913A>G p.N305D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779973742; called by muse, mutect2, varscan2
- CUL7 | c.4502C>T p.A1501V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150715659; called by muse, varscan2
- CUL9 | c.4158C>T p.P1386= | Splice Region (SNP) | VAF 17/37 reads (46%) | catalogued as rs149854957; called by muse, mutect2, varscan2
- CUX1 | c.328G>A p.D110N (on ENST00000292535 / NM_181552.4; = p.D121N on NM_001913.5) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs782612569, COSV52915941; called by muse, mutect2, varscan2
- CWF19L2 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs199671858, COSV56515560; called by muse, mutect2, varscan2
- CWF19L2 | c.2000G>A p.S667N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV56511068; called by muse, mutect2, varscan2
- CX3CR1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866073371; called by muse, mutect2, varscan2
- CXorf58 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs1391932597, COSV64857848; called by muse, mutect2, varscan2
- CXorf65 | c.319+1G>A p.X107_splice | Splice Site (SNP) | VAF 14/116 reads (12%) | catalogued as COSV52147244; called by muse, varscan2
- CXorf65 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV52149949; called by muse, varscan2
- CYB561A3 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99582298; called by muse, mutect2, varscan2
- CYB5R2 | c.647G>T p.R216M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55085597; called by muse, mutect2, varscan2
- CYLC1 | c.1728G>T p.K576N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV100254365; called by muse, mutect2, varscan2
- CYP11A1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773145475, COSV51430875, COSV99165888; called by muse, mutect2
- CYP11B2 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs780112807, COSV59995495; called by muse, mutect2, varscan2
- CYP1A1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs201174966, COSV65697096; called by muse, mutect2, varscan2
- CYP26B1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.761); catalogued as rs754415899, COSV50011512, COSV50013254; called by muse, mutect2, varscan2
- CYP2A6 | c.593T>G p.F198C | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775387934; called by muse, mutect2, varscan2
- CYP2A6 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | catalogued as rs199545200, CM057912; called by muse, mutect2, varscan2
- CYP2C9 | c.1025G>T p.R342M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99583022; called by muse, mutect2, varscan2
- CYP2D6 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs1418365589; called by muse, mutect2
- CYP3A5 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs768530577, COSV99770055; called by muse, mutect2, varscan2
- CYP4A22 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs774570898, COSV53740063; called by muse, mutect2, varscan2
- CYP4F12 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs374928118; called by muse, mutect2, varscan2
- CYP4F3 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.19); catalogued as rs769603208, COSV99657896; called by muse, mutect2, varscan2
- CYP4V2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66505901; called by muse, mutect2, varscan2
- CYP7B1 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761060634; called by muse, mutect2, varscan2
- DAAM1 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV104417250; called by muse, mutect2, varscan2
- DAB1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs559018567, COSV59724209; called by muse, mutect2, varscan2
- DAB2 | c.1645A>C p.S549R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as COSV57915112; called by muse, mutect2, varscan2
- DAB2IP | c.3206C>T p.T1069M (on ENST00000408936; = p.T1041M on NM_032552.3) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1438304708, COSV99405786; called by muse, mutect2, varscan2
- DACH1 | c.1534C>T p.R512C (on ENST00000619232 / NM_001366712.1; = p.R460C on NM_080759.6) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs1360283264, COSV57492480; called by muse, mutect2, varscan2
- DAD1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs542658721, COSV51662729; called by muse, mutect2, varscan2
- DBF4 | c.1929A>G p.I643M | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs370479907; called by muse, mutect2, varscan2
- DCAF1 | c.392A>C p.N131T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs1473202982; called by muse, mutect2, varscan2
- DCAF12L1 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64421388; called by muse, mutect2, varscan2
- DCAF12L2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63583759; called by muse, mutect2, varscan2
- DCAF12L2 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV63580128; called by muse, mutect2, varscan2
- DCAF4 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs771941250, COSV62319294; called by mutect2, varscan2
10,895 further variants in this file (7,758 protein-altering or splice-affecting, 2,837 silent, 300 other) are not listed here.
